Somatic mutation profile of tumor specimen 0DRSSH from CCDI case PBCHET, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.4 years (5,249 days).
Specimen 0DRSSH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2f33599-5896-4ba1-8e86-d27f073f3a31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRSSE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ee11c91-9483-4012-b473-0e71c7dc6730

The open-access MAF lists 24 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 6, Intron 4, 5'UTR 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 192/667 reads (29%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 440/539 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CYB561D1 | c.635T>C p.V212A | Missense Mutation (SNP) | VAF 245/677 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60205007; called by muse, mutect2, varscan2
- OSBPL1A | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 116/532 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.107); catalogued as COSV60196854; called by muse, varscan2
- PARD3B | c.3074G>A p.R1025H (on ENST00000406610 / NM_001302769.2; = p.R956H on NM_057177.7) | Missense Mutation (SNP) | VAF 267/817 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs200533547, COSV62508240; called by muse, mutect2, varscan2
- RAD54L2 | c.2059G>A p.V687I | Missense Mutation (SNP) | VAF 232/725 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs532971546, COSV56577291; called by muse, mutect2, varscan2
- ATRX | c.5417T>A p.I1806N | Missense Mutation (SNP) | VAF 257/343 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ERBB3 | c.3631C>A p.P1211T | Missense Mutation (SNP) | VAF 24/476 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.031); called by muse, mutect2
- GNAS | c.713C>A p.P238Q | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- GRIN2B | c.1893G>A p.M631I | Missense Mutation (SNP) | VAF 263/675 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- PKHD1L1 | c.10516G>T p.D3506Y | Missense Mutation (SNP) | VAF 317/958 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- WDFY3 | c.2311dup p.Y771Lfs*11 | Frame Shift Ins (INS) | VAF 191/693 reads (28%) | called by mutect2, varscan2
- AQR | c.4026A>G p.R1342= | Silent (SNP) | VAF 212/479 reads (44%) | called by muse, mutect2, varscan2
- CDH1 | c.1449C>A p.A483= | Silent (SNP) | VAF 319/501 reads (64%) | called by muse, mutect2, varscan2
- CPSF1 | c.1329C>T p.D443= | Silent (SNP) | VAF 90/431 reads (21%) | catalogued as rs782016878, COSV62939424; called by muse, mutect2, varscan2
- KDR | c.2610G>A p.L870= | Silent (SNP) | VAF 200/8557 reads (2%) | catalogued as COSV55765286; called by muse, mutect2
- SERPINA6 | c.852G>A p.T284= | Silent (SNP) | VAF 250/451 reads (55%) | catalogued as rs774071131, COSV58585426; called by muse, mutect2, varscan2
- WDR62 | c.762C>T p.I254= | Silent (SNP) | VAF 20/732 reads (3%) | called by muse, mutect2
- CYTH4 | c.958-49C>G | Intron (SNP) | VAF 77/248 reads (31%) | called by muse, mutect2, varscan2
- DNAH8 | c.-9G>A | 5'UTR (SNP) | VAF 227/612 reads (37%) | catalogued as rs1369615342; called by muse, mutect2, varscan2
- FIBP | c.-26G>A | 5'UTR (SNP) | VAF 43/104 reads (41%) | called by muse, mutect2, varscan2
- MS4A6A | c.283-30C>A | Intron (SNP) | VAF 183/469 reads (39%) | catalogued as rs746683713; called by muse, mutect2, varscan2
- OSBPL7 | c.703-77A>G | Intron (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- TMEM8B | c.819+126A>G | Intron (SNP) | VAF 117/1154 reads (10%) | called by muse, mutect2
